Gene-level copy-number profile of tumor specimen C3L-03493-54 from CPTAC case C3L-03493, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 65.5 years (23,923 days).
Specimen C3L-03493-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 06ca205d-bd64-4623-8505-4e75507610a0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03493-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/779ec055-03e3-49f6-9a07-5ccdea492eac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 2,872; copy number 2: 56,035; copy number 3: 3.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:127,204–186,136, 3 genes (within-gene range 0–2): LINC01001, AC069287.3, RNU6-447P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
